Gene-level copy-number profile of tumor specimen AP-2XNK-D6 from APOLLO case AP-2XNK, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3.
Specimen AP-2XNK-D6: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7cea52bd-7519-4c9e-91b8-52744f4a22db.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-2XNK-MF (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/f3ebcb94-d6ad-4dae-87f4-15a9d208433e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,360; copy number 2: 42,402; copy number 3: 6,548; copy number 4: 2,126; copy number 5: 1,470.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,470 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–144,068,350, 29 genes, copy number 5: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D.
- chr6:105,919–14,646,638, 264 genes, copy number 5 (broad region; genes not listed).
- chr6:15,246,069–15,522,042, 1 gene, copy number 5 (within-gene range 4–5): JARID2.
- chr6:15,324,367–17,293,871, 24 genes, copy number 5: RNU6-645P, 5S_rRNA, DTNBP1, AL021978.1, ARPC3P5, LINC02543, AL365265.1, MDH1P2, MYLIP, MIR4639, AL021407.2, AL021407.1, MRPL42P2, RNU6-1114P, Y_RNA, GMPR, AL009031.1, ATXN1, ATXN1-AS1, AL137003.1, AL138740.1, STMND1, AL136305.1, RBM24.
- chr6:18,387,350–26,659,752, 162 genes, copy number 5 (broad region; genes not listed).
- chr6:27,780,619–34,696,859, 492 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:34,877,462–58,121,029, 469 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:60,719,222–62,548,272, 12 genes, copy number 5: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1.
- chr6:66,093,431–66,094,909, 1 gene, copy number 5: NUFIP1P1.
- chr12:12,310–38,133, 3 genes, copy number 5: DDX11L8, WASH8P, FAM138D.
- chr20:48,324,812–49,046,168, 13 genes, copy number 5: AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2, RNU7-144P, PREX1, AL035106.1, AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1.

Autosomal genes at a single copy (total copy number 1): 3,658. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
